Gene-level copy-number profile of tumor specimen TCGA-20-1686-01A from TCGA case TCGA-20-1686, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 75.5 years (27,588 days).
Specimen TCGA-20-1686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b56919c1-4fde-47bb-9b85-cf3b41fb51ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-20-1686-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4a20f69-87a5-4766-932b-514ae8745744

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,788; copy number 2: 14,309; copy number 3: 16,927; copy number 4: 17,503; copy number 5: 4,365; copy number 6: 1,432; copy number 7: 626; copy number 8: 968; copy number 9: 278; copy number 10: 218; copy number 11: 97; copy number 12: 9; copy number 13: 101; copy number 17: 11; copy number 21: 46; copy number 22: 4; copy number 27: 133.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-20-1686-01A-01D-0559-01): tumor purity 0.82, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 897 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:77,092,057–79,767,998, 15 genes, copy number 9–12 (within-gene range 3–12): RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923.
- chr4:71,434,405–81,215,117, 157 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:78,805,293–79,314,951, 3 genes, copy number 10 (within-gene range 5–10): AC083837.1, LINC02605, AC138646.1.
- chr8:117,794,490–118,951,885, 6 genes, copy number 11 (within-gene range 7–11): EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B.
- chr8:126,325,454–128,564,679, 36 genes, copy number 9–17: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:133,886,496–137,698,467, 33 genes, copy number 9 (within-gene range 7–9): AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1.
- chr10:119,726,042–122,345,793, 39 genes, copy number 9: INPP5F, RN7SL846P, PHACTR2P1, AL133461.1, MCMBP, SEC23IP, MIR4682, NACAP2, AL355298.1, RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P.
- chr17:212,389–1,830,634, 57 genes, copy number 10: RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4.
- chr17:1,858,039–1,858,446, 1 gene, copy number 10: AC130689.1.
- chr17:27,756,766–29,930,276, 132 genes, copy number 11–21 (within-gene range 8–21) (broad region; genes not listed).
- chr17:29,972,514–29,973,027, 1 gene, copy number 11: AC104982.3.
- chr17:32,970,376–34,174,964, 9 genes, copy number 11–17 (within-gene range 7–22): SPACA3, ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1.
- chr17:33,791,838–34,859,046, 26 genes, copy number 13–22 (within-gene range 7–22): AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:36,861,674–40,284,136, 133 genes, copy number 27 (within-gene range 2–27) (broad region; genes not listed).
- chr19:20,295,089–24,163,425, 170 genes, copy number 9 (broad region; genes not listed).
- chr22:29,603,556–31,207,019, 77 genes, copy number 13 (broad region; genes not listed).
- chr22:31,222,745–31,230,172, 2 genes, copy number 13: RNU6-1128P, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 2,171. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
